TARGET case TARGET-00-RO02380 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/581eb6ac-ec86-43a7-ac33-3f06b8b6ec77

Biospecimens (1 sample)
- Sample TARGET-00-RO02380-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
